Somatic mutation profile of tumor specimen TCGA-DX-A8BJ-01A (aliquot TCGA-DX-A8BJ-01A-11D-A417-09) from TCGA case TCGA-DX-A8BJ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 76.9 years (28,091 days).
Specimen TCGA-DX-A8BJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f2bcd80-0cbe-4085-bef9-5016b5a02724.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BJ-10B (Blood Derived Normal), aliquot TCGA-DX-A8BJ-10B-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/991b6fef-4cab-44d1-aced-a9dee2e79d90

The open-access MAF lists 61 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 38, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANXA7 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV100873497; called by muse, mutect2, varscan2
- BARHL2 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV100966092; called by muse, mutect2
- C8A | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100776565, COSV100776650; called by muse, mutect2
- CBY2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs761413589, COSV60117619; called by muse, mutect2, varscan2
- CCNB3 | c.3332C>T p.T1111I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99329612; called by muse, mutect2, varscan2
- CEP78 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99450799; called by muse, mutect2
- CHEK1 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99629854; called by muse, mutect2, varscan2
- CHTOP | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV100904719; called by muse, mutect2, varscan2
- CLINT1 | c.974A>T p.D325V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV99754550; called by muse, mutect2, varscan2
- CNIH4 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100837038; called by muse, mutect2, varscan2
- CPNE8 | c.1146T>C p.N382= | Splice Region (SNP) | VAF 5/53 reads (9%) | catalogued as rs1565566810, COSV100504968; called by muse, mutect2
- DNAH3 | c.6016G>T p.E2006* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99769937; called by muse, mutect2, varscan2
- DPY19L1 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100204905; called by muse, mutect2, varscan2
- FEZF1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100484540; called by muse, mutect2, varscan2
- HSPA13 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as rs746052483, COSV99580230; called by muse, mutect2, varscan2
- KRT84 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.347); catalogued as rs779594575, COSV57772289, COSV57773706; called by muse, mutect2, varscan2
- LARP1B | c.527A>T p.Y176F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99218793; called by muse, mutect2, varscan2
- LRP1 | c.7854C>G p.I2618M | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676838, COSV99676895; called by muse, mutect2, varscan2
- MPP2 | c.1187T>C p.M396T (on ENST00000461854 / NM_001278372.2; = p.M372T on NM_005374.5) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99290749; called by muse, mutect2, varscan2
- NR4A3 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767254135, COSV100432668; called by muse, varscan2
- OR10G8 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 73/82 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs141086209, COSV101461868, COSV101461894; called by muse, varscan2
- OR2B11 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100276517; called by muse, mutect2, varscan2
- OR8H2 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100542453; called by muse, mutect2, varscan2
- PASD1 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201707889, COSV64856187; called by muse, mutect2, varscan2
- PDCD7 | c.825C>A p.D275E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV99200158; called by muse, mutect2
- PLEKHG5 | c.1642G>A p.V548I (on ENST00000400915 / NM_001042663.3; = p.V511I on NM_020631.6) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1470385932, COSV100557084; called by muse, mutect2
- PPHLN1 | c.1058del p.P353Lfs*2 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | catalogued as COSV56737798; called by mutect2, pindel
- PRDM9 | c.1067G>T p.W356L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99691037; called by muse, mutect2, varscan2
- PSD3 | c.2938C>T p.R980C (on ENST00000440756; = p.R979C on NM_015310.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676669; called by mutect2, varscan2
- RIMBP2 | c.2444C>A p.S815Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV99900221; called by muse, mutect2, varscan2
- SCUBE3 | c.782C>A p.T261N | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV99235085; called by muse, mutect2, varscan2
- SHARPIN | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100010565; called by muse, mutect2, varscan2
- SLC38A10 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs142761487; called by muse, mutect2, varscan2
- SLC5A1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs759726503, COSV56687556; called by muse, mutect2, varscan2
- SVEP1 | c.3775T>G p.S1259A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100238850; called by muse, mutect2, varscan2
- TNR | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs1277584869, COSV99691064; called by muse, mutect2, varscan2
- TRAF7 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); catalogued as COSV100399780, COSV58213941; called by muse, mutect2, varscan2
- TRANK1 | c.7273C>T p.R2425C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs369117311; called by mutect2, varscan2
- TRRAP | c.7672-2A>G p.X2558_splice (on ENST00000359863 / NM_001244580.1; = p.X2540_splice on NM_003496.3) | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100722818; called by muse, mutect2, varscan2
- UGT2B15 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV100592430; called by muse, mutect2, varscan2
- WDR17 | c.3443T>G p.L1148* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99708103; called by muse, mutect2
- ZNF324B | c.789C>G p.S263R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100351771; called by muse, mutect2, varscan2
- NOC3L | c.1130_1156del p.I377_V385del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- PLD1 | c.8_32del p.L3Pfs*11 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- RAP1GDS1 | c.604_613del p.C202Hfs*5 (on ENST00000408927 / NM_001100427.2; = p.C203Hfs*5 on NM_021159.5) | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- SMCHD1 | c.3535_3546del p.Y1179_Q1182del | In Frame Del (DEL) | VAF 29/46 reads (63%) | called by mutect2, pindel, varscan2
- TMEM209 | c.-9_3+13del | Splice Site (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel
- TRGV9 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUBGCP5 | c.2170A>T p.R724W | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCA8 | c.3843A>G p.L1281= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99286655; called by muse, mutect2, varscan2
- ARHGDIB | c.243A>G p.G81= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV99967412; called by muse, mutect2
- BTK | c.1308C>A p.S436= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100437844; called by muse, mutect2, varscan2
- CASR | c.1815G>A p.P605= (on ENST00000490131; = p.P682= on NM_000388.4) | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs760450976, COSV99949357; called by muse, varscan2
- FCGBP | c.7182C>T p.H2394= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs1316672907; called by muse, mutect2
- GPR149 | c.1782C>T p.S594= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101078682; called by muse, mutect2, varscan2
- ITGA6 | c.1170G>T p.V390= (on ENST00000442250; = p.V351= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- MUC5AC | c.51T>C p.A17= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100650669; called by muse, mutect2
- PLEKHA3 | c.765A>G p.E255= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV99317854; called by muse, mutect2, varscan2
- POLR1A | c.768A>G p.L256= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs200970625; called by muse, mutect2, varscan2
- RALYL | c.855G>A p.E285= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV101569404; called by muse, mutect2, varscan2
- TENM3 | c.474A>G p.T158= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as COSV101305402; called by mutect2, varscan2
